Gene-level copy-number profile of specimen HCM-CSHL-0900-C54-85B from HCMI case HCM-CSHL-0900-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC2; FIGO stage: Stage IIIC2; Tumor grade: G3.
Specimen HCM-CSHL-0900-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b47e00b0-fd81-49c1-9e74-8067ec70e95b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0900-C54-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/08722133-fa80-4ae1-af29-3d58884ca989

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,005; copy number 2: 23,206; copy number 3: 18,857; copy number 4: 7,227; copy number 5: 4,083; copy number 6: 3,279; copy number 7: 149; copy number 8: 378; copy number 9: 145; copy number 10: 44; copy number 12: 4; copy number 13: 3; copy number 15: 10; copy number 20: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,098 genes in 91 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,644,547–16,241,398, 114 genes, copy number 5 (broad region; genes not listed).
- chr1:39,838,110–41,043,890, 49 genes, copy number 5 (within-gene range 3–5): TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1.
- chr1:91,680,343–94,121,148, 63 genes, copy number 5 (broad region; genes not listed).
- chr1:102,763,322–113,199,258, 214 genes, copy number 5–8 (broad region; genes not listed).
- chr1:118,264,372–121,580,524, 81 genes, copy number 6 (broad region; genes not listed).
- chr1:150,218,417–151,070,325, 48 genes, copy number 5–7: ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11.
- chr1:155,897,808–156,367,873, 30 genes, copy number 5–6: RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC.
- chr2:38,814–28,338,901, 472 genes, copy number 5 (broad region; genes not listed).
- chr2:28,633,282–43,226,606, 214 genes, copy number 5–6 (broad region; genes not listed).
- chr2:101,309,450–111,523,376, 189 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:111,295,629–113,962,596, 88 genes, copy number 5–6 (broad region; genes not listed).
- chr3:134,313,576–185,489,094, 799 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr3:196,867,856–198,123,232, 42 genes, copy number 5: SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr6:2,887,270–40,387,590, 1,092 genes, copy number 5–7 (broad region; genes not listed).
- chr7:73,403,788–74,254,458, 28 genes, copy number 5: Y_RNA, FZD9, BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1, VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270, AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2.
- chr7:116,237,929–118,004,045, 48 genes, copy number 5–8 (within-gene range 3–8): AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1.
- chr8:46,028,804–144,047,114, 1,421 genes, copy number 5–9 (broad region; genes not listed).
- chr9:128,371,361–128,772,414, 25 genes, copy number 6: URM1, AL359091.1, MIR219A2, MIR219B, CERCAM, AL359091.4, AL359091.2, ODF2, ODF2-AS1, GLE1, AL356481.1, RNU7-171P, SPTAN1, AL356481.2, AL356481.3, DYNC2I2, VTI1BP4, HMGA1P4, SET, PKN3, RN7SL560P, ZDHHC12, AL441992.1, ZER1, Metazoa_SRP.
- chr9:136,612,024–138,253,217, 109 genes, copy number 5–10 (broad region; genes not listed).
- chr10:125,683,229–133,778,699, 142 genes, copy number 5 (broad region; genes not listed).
- chr11:64,917,553–65,242,757, 32 genes, copy number 6: PPP2R5B, GPHA2, MAJIN, BATF2, ARL2, ARL2-SNX15, MIR6879, AP000436.1, SNX15, SAC3D1, NAALADL1, CDCA5, ZFPL1, TMEM262, VPS51, AP003068.1, TM7SF2, ZNHIT2, AP003068.3, AP003068.4, FAU, SYVN1, MRPL49, MIR6751, HIGD1AP10, RNU2-23P, PDCL2P2, SPDYC, PGAM1P8, AP003068.2, CAPN1, SLC22A20P.
- chr12:53,326,575–53,898,976, 23 genes, copy number 5 (within-gene range 4–5): SP7, SP1, AMHR2, PRR13, AC023509.1, PCBP2, PCBP2-OT1, AC023509.4, MAP3K12, AC023509.3, TARBP2, ATF7-NPFF, NPFF, ATF7, AC023509.2, AC023509.6, AC023509.5, ATP5MC2, AC073594.1, CALCOCO1, AC076968.2, CISTR, AC076968.1.
- chr12:56,101,331–56,413,190, 32 genes, copy number 6 (within-gene range 4–6): AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2.
- chr15:101,334,437–101,979,093, 30 genes, copy number 5: PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:21,376,648–26,137,685, 120 genes, copy number 5–7 (broad region; genes not listed).
- chr17:38,297,023–38,921,770, 31 genes, copy number 5–7 (within-gene range 4–7): MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1.
- chr17:42,682,531–42,940,702, 23 genes, copy number 5–8 (within-gene range 4–8): CNTNAP1, AC100793.3, EZH1, MIR6780A, AC100793.1, AC100793.4, HMGN2P15, RAMP2-AS1, RAMP2, VPS25, WNK4, COA3, CNTD1, BECN1, MIR6781, PSME3, AOC2, AOC3, AOC4P, LINC00671, RNU6-287P, G6PC, AC055866.1.
- chr17:57,861,243–58,328,795, 23 genes, copy number 6 (within-gene range 4–6): CUEDC1, AC015845.1, AC015813.4, VEZF1, AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5, AC015813.3, DYNLL2, AC015813.6, OR4D1, MSX2P1, OR4D2, EPX, AC005962.1, MKS1, LPO, AC005962.2, AC004687.3, MPO, TSPOAP1.
- chr17:64,319,415–80,477,843, 453 genes, copy number 5–15 (broad region; genes not listed).
- chr18:45,034–27,595,164, 499 genes, copy number 5–10 (broad region; genes not listed).
- chr18:58,416,765–59,359,265, 30 genes, copy number 5: AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P, OACYLP, AC040963.1, SEC11C, GRP, RAX, CPLX4, LMAN1.
- chr19:2,595,019–3,469,217, 40 genes, copy number 5: RN7SL121P, AC092068.2, MIR7850, AC092068.1, AC092068.3, AC006538.3, DIRAS1, AC006538.2, AC006538.4, AC006538.1, SLC39A3, SGTA, THOP1, ZNF554, ZNF555, AC006130.1, ZNF556, AC006130.2, AC119403.2, ZNF57, AC119403.1, ZNF77, AC006277.1, TLE6, TLE2, AC005944.1, TLE5, GNA11, AC005262.2, KF456478.1, AC005262.1, GNA15, AC005264.1, S1PR4, NCLN, CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1.
- chr19:6,343,761–7,087,968, 47 genes, copy number 5: AC011491.3, CLPP, ALKBH7, PSPN, GTF2F1, AC011491.2, MIR6885, MIR6790, AC011491.1, KHSRP, MIR3940, SLC25A41, SLC25A23, CRB3, DENND1C, AC010503.4, TUBB4A, AC010503.2, AC010503.1, TNFSF9, AC010503.3, CLIC4P2, Y_RNA, CD70, RPL7P50, TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557.
- chr19:10,553,085–20,331,517, 559 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr19:27,793,431–36,850,787, 292 genes, copy number 6–8 (within-gene range 1–8) (broad region; genes not listed).
- chr19:37,075,113–38,208,369, 37 genes, copy number 7 (within-gene range 2–7): AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1.
- chr19:49,017,496–49,961,172, 95 genes, copy number 6 (broad region; genes not listed).
- chr21:44,768,580–46,665,124, 69 genes, copy number 5–6 (broad region; genes not listed).
- chr22:20,689,929–21,284,161, 36 genes, copy number 5–7: POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P.
- chr22:29,767,091–30,907,824, 48 genes, copy number 6–7 (within-gene range 2–7): AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2, SLC35E4, DUSP18, AC003072.1, AC003072.2, OSBP2, MIR3200.

Autosomal genes at a single copy (total copy number 1): 1,005. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
